Somatic mutation profile of tumor specimen MMRF_1505_1_BM_CD138pos (aliquot MMRF_1505_1_BM_CD138pos_T1_KBS5U_L05772) from MMRF case MMRF_1505, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,885 days).
Specimen MMRF_1505_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c953d8fb-f9ff-42ab-b551-f0d7e1d95cb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1505_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1505_1_PB_Whole_C2_KBS5U_L05792; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0f05a6d-7bd4-43b4-9e09-78b757a549ca

The open-access MAF lists 92 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 27, Silent 14, Intron 12, Nonsense Mutation 2, 5'UTR 2, 3'Flank 2, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 95/198 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ALDOA | c.568G>C p.A190P (on ENST00000642816 / NM_001243177.4; = p.A136P on NM_184041.5) | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57633499; called by muse, mutect2, varscan2
- ANKRD30B | c.971C>T p.T324I | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV62816835; called by muse, mutect2, varscan2
- CASP5 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760261601; called by muse, mutect2, varscan2
- GCNT1 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65059135; called by muse, mutect2, varscan2
- GOLGA4 | c.5371C>T p.Q1791* | Nonsense Mutation (SNP) | VAF 74/150 reads (49%) | catalogued as COSV62711155; called by muse, mutect2, varscan2
- HEPN1 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1442886731; called by muse, mutect2, varscan2
- IGHJ6 | c.15C>G p.Y5* | Nonsense Mutation (SNP) | VAF 39/54 reads (72%) | catalogued as rs1156371941; called by muse, varscan2
- IGHV1-69 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as rs782247418; called by muse, mutect2, varscan2
- IGHV2-70 | c.153T>A p.S51R | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs368987043; called by muse, varscan2
- IGLV3-1 | c.238T>C p.F80L | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs561290535; called by muse, varscan2
- ROBO1 | c.3908G>A p.R1303Q | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.209); catalogued as rs761320548; called by muse, mutect2, varscan2
- SIDT1 | c.1304G>A p.R435K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as rs778923517; called by muse, mutect2, varscan2
- THRSP | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55246402; called by muse, mutect2, varscan2
- TMPRSS4 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752500740, COSV71108724; called by muse, mutect2, varscan2
- ZNF710 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as rs548609306; called by muse, mutect2, varscan2
- ZNF831 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV64040656; called by muse, mutect2, varscan2
- CDKL3 | c.414T>G p.I138M | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CENPU | c.1144-2A>G p.X382_splice | Splice Site (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- CHAF1A | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTTNBP2 | c.3294T>A p.S1098R | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DPYSL2 | c.310del p.R104Gfs*20 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel, varscan2
- ERAP2 | c.937T>A p.Y313N | Missense Mutation (SNP) | VAF 67/132 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNA3 | c.1563C>A p.N521K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LCMT2 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 91/181 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NFKBIZ | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POGLUT1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKD2 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM33 | c.3148G>A p.G1050R | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TEK | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRPC4 | c.1276C>A p.L426I | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- VPS52 | c.1727T>A p.M576K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.705); called by muse, mutect2
- XRCC5 | c.1634A>G p.K545R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2
- ZKSCAN3 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- AL121899.2 | c.771C>T p.S257= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs201594514, COSV67350013; called by muse, mutect2, varscan2
- CATSPER4 | c.576T>C p.H192= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs377514068; called by muse, mutect2, varscan2
- CCDC151 | c.210G>A p.Q70= | Silent (SNP) | VAF 62/114 reads (54%) | called by muse, mutect2, varscan2
- CFAP74 | c.1356G>A p.E452= | Silent (SNP) | VAF 40/98 reads (41%) | called by muse, mutect2, varscan2
- ELMO1 | c.546G>A p.K182= | Silent (SNP) | VAF 71/148 reads (48%) | called by muse, mutect2, varscan2
- GGT6 | c.543G>A p.A181= (on ENST00000574154 / NM_001122890.3; = p.A149= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs576200908; called by muse, mutect2, varscan2
- IGHV2-70 | c.189G>T p.G63= | Silent (SNP) | VAF 75/147 reads (51%) | catalogued as rs112642180; called by muse, varscan2
- IGHV2-70D | c.261G>A p.R87= | Silent (SNP) | VAF 36/80 reads (45%) | called by muse, varscan2
- IL21R | c.837C>T p.P279= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100560695; called by muse, mutect2, varscan2
- MEX3A | c.930C>T p.D310= | Silent (SNP) | VAF 40/273 reads (15%) | called by muse, mutect2, varscan2
- SELE | c.1311G>A p.P437= | Silent (SNP) | VAF 156/230 reads (68%) | catalogued as rs144324234; called by muse, mutect2, varscan2
- TRAPPC10 | c.1893C>T p.F631= | Silent (SNP) | VAF 55/121 reads (45%) | called by muse, mutect2, varscan2
- VWA1 | c.462C>G p.P154= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV58599776; called by muse, mutect2
- XYLT1 | c.1875G>A p.P625= | Silent (SNP) | VAF 98/197 reads (50%) | catalogued as rs182016158; called by muse, mutect2, varscan2
- ABHD10 | c.*305C>T | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, varscan2
- AFF1 | c.*2375T>A | 3'UTR (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- ALB | c.1191+17A>G | Intron (SNP) | VAF 76/150 reads (51%) | called by muse, mutect2, varscan2
- ATRN | c.*3914C>T | 3'UTR (SNP) | VAF 41/77 reads (53%) | catalogued as COSV99496762; called by muse, mutect2, varscan2
- CA5B | c.*61T>A | 3'UTR (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- CACNA1I | c.*1037C>T | 3'UTR (SNP) | VAF 57/100 reads (57%) | catalogued as rs1245756622; called by muse, mutect2, varscan2
- CALHM3 | c.*81G>A | 3'UTR (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- CNR1 | c.*2883dup | 3'UTR (INS) | VAF 29/65 reads (45%) | called by mutect2, varscan2
- CTSH | c.406-1106T>C | Intron (SNP) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- DCAF16 | c.-216G>C | 5'UTR (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- DCAF4L2 | c.*599T>A | 3'UTR (SNP) | VAF 69/137 reads (50%) | called by muse, mutect2, varscan2
- DEPDC1B | c.*266A>T | 3'UTR (SNP) | VAF 13/126 reads (10%) | called by muse, varscan2
- DEPDC1B | c.*147A>C | 3'UTR (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- DHRS4L2 | c.129-71C>A | Intron (SNP) | VAF 14/88 reads (16%) | catalogued as rs777644237; called by muse, mutect2, varscan2
- ETV1 | chr7:13894025 T>G | 3'Flank (SNP) | VAF 38/94 reads (40%) | catalogued as rs963580565; called by muse, mutect2, varscan2
- EVI2A | chr17:31316955 G>C | 3'Flank (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- H6PD | c.*2731G>A | 3'UTR (SNP) | VAF 65/143 reads (45%) | called by muse, mutect2, varscan2
- HINFP | c.524-25G>A | Intron (SNP) | VAF 21/29 reads (72%) | called by muse, mutect2, varscan2
- IFT74 | c.121-1489A>G | Intron (SNP) | VAF 79/165 reads (48%) | called by muse, mutect2, varscan2
- KCTD10 | c.387+31G>A | Intron (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- LYN | c.-247_-220del | 5'UTR (DEL) | VAF 24/58 reads (41%) | called by mutect2, pindel
- MEIS1 | c.*1273del | 3'UTR (DEL) | VAF 11/35 reads (31%) | catalogued as rs976507976; called by mutect2, varscan2
- MKRN3 | chr15:23562113 C>T | 5'Flank (SNP) | VAF 53/102 reads (52%) | called by muse, mutect2, varscan2
- NTRK3 | c.1586-38459C>T | Intron (SNP) | VAF 46/101 reads (46%) | catalogued as rs1004406415; called by muse, mutect2, varscan2
- OPCML | c.*4148A>C | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- PLEKHA2 | c.*1896G>A | 3'UTR (SNP) | VAF 13/32 reads (41%) | catalogued as rs986174922; called by muse, mutect2, varscan2
- PRDM1 | c.*1268A>G | 3'UTR (SNP) | VAF 36/79 reads (46%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.*668G>A | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2
- RAB3B | c.*11947T>C | 3'UTR (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-748C>T | Intron (SNP) | VAF 34/93 reads (37%) | catalogued as rs781275279; called by muse, mutect2, varscan2
- RMDN3 | c.1225-9T>C | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- SAFB2 | c.2394+20C>T | Intron (SNP) | VAF 56/95 reads (59%) | called by mutect2, varscan2
- SCRT2 | c.*798G>A | 3'UTR (SNP) | VAF 62/108 reads (57%) | called by muse, mutect2, varscan2
- SEMA3A | c.*553C>T | 3'UTR (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- SLC39A10 | c.*1610A>G | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- SLC6A15 | c.*999T>A | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- SLC7A5 | c.*2075T>C | 3'UTR (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- SMAD4 | c.*6182T>G | 3'UTR (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- TAFA4 | c.*806C>A | 3'UTR (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- TMEM67 | c.*1119C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- TTN | c.10360+3520T>C | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
- UHMK1 | c.*3116C>A | 3'UTR (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- ZNF681 | c.*3199T>A | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.165+254A>G | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
